Surgical pathology report (de-identified scan), TCGA case TCGA-36-2551, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2551-01A (Primary Tumor).

[page 1 of 4]
TCGA-36-2551

Surgical Pathology Consultation Report

Case Number

Collect Date:

Receive Date:

Date Reported

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Right ovary and tube showing:

1. High-grade serous carcinoma with extensive ovarian involvement including ovarian surface, consistent with ovarian primary.
2. Fallopian tube showing involvement by high-grade serous carcinoma.
3. Lymphatic invasion in paratubal lymphatics.

B. Specimen labelled CUL-DE-SAC showing high-grade serous carcinoma.

C. Specimen labelled LEFT OVARY AND UTERUS:

1. High-grade serous carcinoma involving left ovary and fallopian tube.
2. Lymphatic invasion of paratubal lymphatics.
3. Endometrial polyp with high-grade non-invasive serous carcinoma; otherwise the endometrium is inactive and unremarkable.
4. Unremarkable cervix.

D. Specimen labelled PELVIC MASS, TRANSVERSE COLON, SPLENIC FLEXURE showing:

1. Metastatic high-grade serous carcinoma involving the bowel serosa and colonic fat.

[page 2 of 4]
2. Colon otherwise negative for tumor.
3. Multiple benign lymph nodes.

E. Specimen labelled OMENTUM showing extensive involvement by high-grade serous carcinoma.

F. Specimen labelled RIGHT COLON showing:

1. Transmural involvement of colon up to mucosa by high-grade serous carcinoma, including widespread lymphatic invasion.
2. Distal margin positive for tumor; the proximal margin is free of tumor.
3. Appendix showing serosal involvement by tumor.
4. Five benign lymph nodes.

G. Cytology [REDACTED] Positive for high-grade serous carcinoma.

Clinical History as Provided by Submitting Physician:

Corresponding cytology [REDACTED]

Pelvic mass

- A. (R) ovary
- B. Tumour from cul-de-sac
- C. (L) ovary and uterus
- D. Pelvic mass -transverse colon -splenic flexure
- E. Omentum
- F. (R) colon

Specimens Received:

- A: right ovary
- B: tumor from cul de sac
- C: left ovary + uterus
- D: pelvic mass + transverse colon + splenic flexure
- E: omentum
- F: right colon

[page 3 of 4]
Gross Description:

The specimen is received in six containers each labelled with the patient's demographics.

Container A is labelled RIGHT OVARY and consists of adnexa including fallopian tube measuring 4 cm in length and 0.5 cm in diameter, and ovary measuring 3.5 x 2.5 x 1.5 cm. The serosal surface shows diffuse papillary growth. Black ink is focally applied on the external surface. Representative sections are submitted as follows:

A1 -frozen section block

A2-A3 -ovary

A4 -fallopian tube

Container B is labelled TUMOUR FROM CUL-DE-SAC and consists of fragments of tumour mass aggregating to 5.5 x 5 x 1 cm. Cross section of the specimen shows whitish homogeneous structure. Representative sections are submitted in cassettes B1-B3.

Container C is labelled LEFT OVARY AND UTERUS and consists of the same weighing 69 g. The uterus measures 7.5 x 4.2 x 3.2 cm. The left fallopian tube measures 5 cm in length and 0.4 cm in diameter. The left ovary measures 2.8 x 1.9 x 1.1 cm. The serosal surface of the left ovary shows papillary growth. The cervix measures 2.7 cm in length and 2.8 cm in diameter. The mucosa of the exocervix is normal.

The bivalved uterus shows several nabothian-like cysts of the endocervical canal. The endometrium is even with a thickness of 0.1 cm. The myometrium is symmetrical with a maximal thickness of 2.1 cm. Cross section of the left ovary shows papillary growth. Representative sections are submitted as follows:

C1-C2 -cervix, anterior/posterior

C3 -cul-de-sac

C4-C5 -isthmus, anterior/posterior

C6-C7 -anterior myometrium

C8 -posterior myometrium

C9-C10 -left ovary

C11 -fallopian tube

Container D is labelled PELVIC MASS PLUS TRANSVERSE COLON PLUS SPLENIC FLEXURE and consists of a 27 cm long segment of bowel with either end stapled measuring 7 cm in circumference at the proximal end and 5.5 cm in circumference at the distal end. The mesentery of the colon is distorted by tumour mass measuring 24 x 7 x 3 cm. The bowel is opened longitudinally. The mucosal aspect is unremarkable. Cross section of the mesentery shows tan-white tumour mass with areas of punctate hemorrhage. Representative sections are submitted as follows:

D1 -proximal margin, perpendicular section

[page 4 of 4]
D2 -distal margin, perpendicular section
D3-D5 -tumour in relation to bowel wall
D6 -omentum

Container E is labelled OMENTUM and consists of tumour mass measuring 21 x 15 x 4 cm. Cross section of the specimen shows yellowish tumour mass. Representative sections are submitted in cassettes E1-E3.

Container F is labelled RIGHT COLON and consists of a right hemicolectomy including terminal ileum measuring 10 cm in length and 4.5 cm in circumference at the proximal stapled end, cecum/ascending colon measuring 23 cm in length and 9.5 cm in circumference for cecum, 6.5 cm in circumference for the distal stapled end. The appendix measures 6.5 cm in length and 0.6 cm in diameter. The serosal surface shows numerous whitish nodules ranging in size from 0.1 up to 0.5 cm. The bowel is opened longitudinally. The mucosal aspect shows an area of mucosal puckering measuring 4.5 x 1.2 cm that is 5 cm from the distal resection margin. Cross section of the bowel wall shows slightly thickened indurated mucosa. Representative sections are submitted as follows:

F1-F3 -area of mucosal puckering
F4 -ileocecal valve
F5 -distal margin, perpendicular section
F6 -proximal margin, perpendicular section
F7 -appendix
F8 -lymph nodes, each fragment of tissue represents one lymph node

[REDACTED]

Intraoperative Consultation:

[REDACTED]

Gross Description: 3.5 x 3 x 1.5 cm (N) appearing tube with papillary mass of ovary -3 cm. FS as A1.

Provisional Diagnosis: High-grade serous carcinoma.

[REDACTED]

Copies to: [REDACTED]

Source: NCI Genomic Data Commons file 894e80ee-00a4-44d5-b199-eaf8d52a4ef3 (TCGA-36-2551.C3E022A3-B58D-437B-A990-691730E9DAF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).